Somatic mutation profile of tumor specimen MP2PRT-PATZWF-TMP1-A (aliquot MP2PRT-PATZWF-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATZWF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,908 days).
Specimen MP2PRT-PATZWF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2a35660-0d51-4443-a591-20d6c1e74c6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATZWF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATZWF-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c6b1d07-69dc-464a-840f-abe397b86701

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DBH | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 236/582 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs13306306, COSV55042600; called by muse, mutect2, varscan2
- DNAH9 | c.3370G>A p.A1124T | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs777317191, COSV52352626; called by muse, mutect2, varscan2
- IGSF5 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 182/497 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs749337072, COSV101012063; called by muse, mutect2, varscan2
- KRT71 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 177/424 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as rs769963433, COSV99921946; called by muse, mutect2, varscan2
- PSAPL1 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 32/585 reads (5%) | catalogued as rs1464100123; called by muse, mutect2
- THSD4 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 222/648 reads (34%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.942); catalogued as COSV99965805; called by muse, mutect2, varscan2
- UBA2 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55828644; called by muse, mutect2, varscan2
- ACSS3 | c.1175C>A p.T392K | Missense Mutation (SNP) | VAF 34/539 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LCT | c.4492C>T p.Q1498* | Nonsense Mutation (SNP) | VAF 89/263 reads (34%) | called by muse, mutect2, varscan2
- RFTN2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MCF2 | c.972C>T p.T324= | Silent (SNP) | VAF 12/399 reads (3%) | catalogued as rs1569360351, COSV58487144; called by muse, mutect2
